Somatic mutation profile of tumor specimen 0DFXH5 from CCDI case PBBRET, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.5 years (4,934 days).
Specimen 0DFXH5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 018edb5d-380e-4759-8501-5013744ed123.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXF3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1736068-960d-4281-9144-9fd3553fbbca

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 3, Silent 3, Nonsense Mutation 1, 5'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 224/608 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CAMSAP3 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 46/1162 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.52); catalogued as rs375404607; called by muse, mutect2
- MAGEE1 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 483/1119 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782397816, COSV100819528, COSV63910611; called by muse, mutect2, varscan2
- PLP1 | c.454-1G>T p.X152_splice | Splice Site (SNP) | VAF 173/443 reads (39%) | catalogued as CS083965, CS102501, CS930860; called by muse, mutect2, varscan2
- RGS11 | c.863C>T p.T288M (on ENST00000397770 / NM_183337.3; = p.T267M on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/783 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs148856124, COSV51454147; called by muse, mutect2
- SORCS2 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 130/1190 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs369677353; called by muse, mutect2, varscan2
- ATP2B3 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 51/1306 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- CAND1 | c.3392C>T p.S1131F | Missense Mutation (SNP) | VAF 67/1933 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- CCDC102A | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 37/1303 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- EGF | c.1751T>A p.L584* | Nonsense Mutation (SNP) | VAF 22/754 reads (3%) | called by muse, mutect2
- GLI2 | c.4036A>G p.T1346A (on ENST00000361492 / NM_001374353.1; = p.T1363A on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 414/1017 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- NF1 | c.3533_3534del p.T1178Ifs*16 | Frame Shift Del (DEL) | VAF 294/537 reads (55%) | called by mutect2, pindel, varscan2
- NKX3-2 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 21/861 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PRR32 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 658/1590 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TMEM249 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 34/912 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); called by muse, mutect2
- MAGEB17 | c.540C>G p.G180= | Silent (SNP) | VAF 104/780 reads (13%) | called by muse, mutect2, varscan2
- PLXNB2 | c.3651C>T p.V1217= | Silent (SNP) | VAF 50/1348 reads (4%) | called by muse, mutect2
- PRRT4 | c.1611C>T p.G537= | Silent (SNP) | VAF 22/660 reads (3%) | called by muse, mutect2
- AIP | c.468+25C>T | Intron (SNP) | VAF 33/1083 reads (3%) | called by muse, mutect2
- DENND1A | c.-20C>T | 5'UTR (SNP) | VAF 50/504 reads (10%) | called by muse, mutect2, varscan2
- DOCK5 | c.3123+68G>A | Intron (SNP) | VAF 14/450 reads (3%) | called by muse, mutect2
- ERBIN | c.818-44C>G | Intron (SNP) | VAF 98/427 reads (23%) | catalogued as rs1381549038; called by muse, mutect2, varscan2
